Somatic mutation profile of tumor specimen BA3110D (aliquot aq-BA3110D) from BEATAML1.0 case 2713, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.4 years (18,784 days).
Specimen BA3110D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b6eeddb-f67b-4f11-bc54-e52cfa11b395.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3323D (Solid Tissue Normal), aliquot aq-BA3323D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9afdb15f-6b54-45d2-a951-13de2afe8a10

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C19orf44 | c.1863G>A p.A621= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as rs200953055; called by muse, mutect2, varscan2
